Somatic mutation profile of tumor specimen TCGA-49-AAR9-01A (aliquot TCGA-49-AAR9-01A-21D-A410-08) from TCGA case TCGA-49-AAR9, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.6 years (22,510 days).
Specimen TCGA-49-AAR9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c93bff7d-fd6e-4ca5-b513-77c5b780e314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AAR9-11A (Solid Tissue Normal), aliquot TCGA-49-AAR9-11A-11D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/854db6d2-83a0-4c8a-9223-d955b6390f9f

The open-access MAF lists 708 somatic variants for this specimen: 536 protein-altering or splice-affecting, 159 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 459, Silent 159, Nonsense Mutation 37, Frame Shift Del 16, Splice Site 11, Intron 7, Splice Region 7, RNA 5, Frame Shift Ins 3, In Frame Del 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC6A1 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1131691302, COSV99822327; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 43/55 reads (78%) | catalogued as COSV99367672; called by muse, mutect2, varscan2
- ABCA1 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101035480, COSV66060131; called by muse, mutect2, varscan2
- ABCA10 | c.3260G>T p.G1087V | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV99287687; called by muse, mutect2, varscan2
- ABCA5 | c.1267+1G>A p.X423_splice | Splice Site (SNP) | VAF 81/225 reads (36%) | catalogued as COSV101200935; called by muse, mutect2, varscan2
- ABCC12 | c.1841C>A p.A614D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100252070; called by muse, mutect2, varscan2
- ABCD2 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV100429093; called by muse, mutect2, varscan2
- AC005833.1 | c.1458C>A p.C486* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV52894219, COSV99362390; called by muse, mutect2, varscan2
- AC005833.1 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); catalogued as COSV52899804; called by muse, mutect2, varscan2
- ACSM2B | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100312238; called by muse, mutect2, varscan2
- ACTA1 | c.192A>T p.R64S | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100796691; called by muse, mutect2, varscan2
- ACTN2 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV100856489; called by muse, mutect2, varscan2
- ADAMTS3 | c.2273A>C p.Q758P | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99709994; called by muse, mutect2, varscan2
- ADAMTS9 | c.2814-1G>T p.X938_splice | Splice Site (SNP) | VAF 96/206 reads (47%) | catalogued as COSV99898532; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3857C>A p.P1286H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs1447973910, COSV101001125; called by muse, mutect2, varscan2
- ADCY2 | c.2593G>T p.A865S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100601524; called by muse, mutect2, varscan2
- ADGRA1 | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV101658573; called by muse, mutect2, varscan2
- ADGRD1 | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs1462840070, COSV99893703; called by muse, mutect2, varscan2
- ADGRG4 | c.423G>T p.R141S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV54953381, COSV99794162; called by muse, mutect2, varscan2
- ADSS2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100836784; called by muse, mutect2, varscan2
- AHCTF1 | c.6854G>C p.R2285T (on ENST00000366508; = p.R2259T on NM_015446.5) | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100403011; called by muse, mutect2
- AHCY | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV99463922; called by muse, mutect2, varscan2
- AJM1 | c.2233C>A p.L745M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454054794, COSV56032804, COSV99915345; called by muse, mutect2, varscan2
- ANKRD27 | c.2096C>G p.A699G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100042492; called by muse, mutect2, varscan2
- ANKRD34A | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1553761144, COSV100041106; called by muse, mutect2, varscan2
- AP1G1 | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1047535330, COSV100249969; called by muse, mutect2, varscan2
- APOB | c.9445G>T p.D3149Y | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV51934474, COSV51935706; called by muse, mutect2, varscan2
- AQP10 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); catalogued as rs768207751, COSV61476104; called by muse, mutect2, varscan2
- ARHGAP12 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100260300; called by muse, mutect2, varscan2
- ARHGAP25 | c.151G>T p.G51C (on ENST00000409202 / NM_001007231.3; = p.G44C on NM_014882.3) | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770925; called by muse, mutect2, varscan2
- ARPP21 | c.817A>T p.R273* | Nonsense Mutation (SNP) | VAF 16/23 reads (70%) | catalogued as rs1277976160, COSV99490610; called by muse, mutect2, varscan2
- ARSG | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV101477866; called by muse, mutect2, varscan2
- ASTN1 | c.1845C>A p.F615L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV56067117, COSV99920179; called by muse, mutect2, varscan2
- ASTN1 | c.364A>C p.I122L | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV99920181; called by muse, mutect2, varscan2
- ATF7IP | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99661093; called by muse, mutect2, varscan2
- AXIN2 | c.2380C>A p.Q794K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.885); catalogued as COSV100195819; called by muse, mutect2, varscan2
- B4GALNT2 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); catalogued as rs1193973526, COSV100302356; called by muse, mutect2, varscan2
- BCORL1 | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV54390670, COSV99498258; called by muse, mutect2, varscan2
- BMPR1B | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99215271; called by muse, mutect2, varscan2
- BRWD3 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981647877, COSV100955586; called by muse, mutect2, varscan2
- BTNL9 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV100576071; called by muse, mutect2, varscan2
- C1QTNF1 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV100189693; called by muse, mutect2, varscan2
- C2CD3 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100486163, COSV58089358; called by muse, mutect2, varscan2
- C2orf16 | c.2501T>C p.L834P | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100820620; called by muse, mutect2, varscan2
- C3AR1 | c.225G>T p.L75F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1296208737, COSV99368019; called by muse, mutect2, varscan2
- C8orf33 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752378676, COSV58895812; called by muse, mutect2, varscan2
- CACNA1A | c.3244T>A p.S1082T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV100800480; called by muse, mutect2, varscan2
- CACNA1S | c.5014A>T p.N1672Y | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); catalogued as COSV100754567; called by muse, mutect2, varscan2
- CADM1 | c.1138G>T p.V380F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100522041; called by muse, mutect2, varscan2
- CALCRL | c.853A>T p.S285C | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101130862; called by muse, mutect2, varscan2
- CAPRIN2 | c.1618A>G p.K540E | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs755030479, COSV99195404; called by muse, mutect2, varscan2
- CARMIL3 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1266073139, COSV100549119; called by muse, mutect2, varscan2
- CASKIN1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100623751; called by muse, mutect2, varscan2
- CCDC105 | c.676-1G>A p.X226_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99479694; called by muse, mutect2, varscan2
- CCDC17 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1474265202, COSV99321840; called by muse, mutect2, varscan2
- CCDC93 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV100098267, COSV60125498; called by muse, mutect2, varscan2
- CCNDBP1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100281468; called by muse, mutect2, varscan2
- CCSER2 | c.2115T>A p.S705R | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99825362; called by muse, mutect2, varscan2
- CDC16 | c.1519G>C p.G507R | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99372642; called by muse, mutect2, varscan2
- CDH19 | c.1828G>T p.G610W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100050683; called by muse, mutect2, varscan2
- CDH23 | c.6133G>T p.D2045Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM010181, COSV99818476; called by muse, mutect2, varscan2
- CDH9 | c.1242C>G p.N414K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99141281; called by muse, mutect2, varscan2
- CDK12 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71002939; called by muse, mutect2, varscan2
- CDKN2A | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs146179135, CM994498, COSV58701950, COSV58703805; called by muse, varscan2
- CDKN2A | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs137854598, CM1414338, COSV58689032, COSV58690567; ClinVar: uncertain significance; called by muse, varscan2
- CELSR1 | c.7130C>A p.T2377K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs755503725, COSV99416485; called by muse, mutect2, varscan2
- CENPE | c.8060G>T p.W2687L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV99476799; called by muse, mutect2, varscan2
- CEP120 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100070727, COSV60269273; called by muse, mutect2, varscan2
- CEP128 | c.94_110del p.L32Yfs*33 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs1434241185; called by mutect2, pindel
- CEP162 | c.578A>T p.Y193F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100002304; called by muse, mutect2, varscan2
- CFAP92 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 13/18 reads (72%) | catalogued as rs1251214840, COSV99414540; called by muse, mutect2, varscan2
- CFH | c.3329G>T p.G1110V | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV66408387, COSV66408888; called by muse, varscan2
- CHRNA10 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as rs370949315, COSV99167106; called by muse, mutect2, varscan2
- CHSY3 | c.2423T>G p.V808G | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518312; called by muse, mutect2, varscan2
- CHURC1 | c.315G>T p.M105I (on ENST00000549115 / NM_001204063.1; = p.M106I on NM_145165.3) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100767393; called by muse, mutect2, varscan2
- CKAP5 | c.3917G>T p.R1306L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100370301; called by muse, mutect2, varscan2
- CKMT1A | c.925C>A p.R309S | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100787696, COSV100787734; called by muse, mutect2, varscan2
- CLCN1 | c.2485G>T p.V829L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV100577639; called by muse, mutect2, varscan2
- CNNM1 | c.2107A>T p.I703F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs1042273504, COSV100763753; called by muse, mutect2, varscan2
- CNST | c.693A>T p.Q231H | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100829780; called by muse, mutect2, varscan2
- CNTLN | c.3114G>T p.K1038N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV99262503; called by muse, mutect2, varscan2
- CNTN5 | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99672052; called by muse, mutect2, varscan2
- CPEB3 | c.1169G>C p.R390P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56455947, COSV99798277; called by muse, mutect2, varscan2
- CRMP1 | c.874A>G p.S292G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV100271236; called by muse, mutect2
- CSMD3 | c.5448G>T p.E1816D (on ENST00000297405 / NM_001363185.1; = p.E1712D on NM_052900.3) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV99822278; called by muse, mutect2, varscan2
- CSMD3 | c.3572G>T p.G1191V (on ENST00000297405 / NM_001363185.1; = p.G1087V on NM_052900.3) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1441385922, COSV99822281; called by muse, mutect2, varscan2
- CSMD3 | c.3206G>T p.G1069V (on ENST00000297405 / NM_001363185.1; = p.G965V on NM_052900.3) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822282; called by muse, mutect2, varscan2
- CSMD3 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99822283; called by muse, mutect2, varscan2
- CSPG4 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217219364, COSV100413268; called by muse, mutect2, varscan2
- CTDP1 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99310036; called by muse, mutect2, varscan2
- CTDSPL2 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99526436; called by muse, mutect2, varscan2
- CTNNA1 | c.2177T>G p.M726R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100242022, COSV57072646, COSV57077329; called by muse, mutect2, varscan2
- CTNNA2 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63560629, COSV63587504; called by muse, mutect2, varscan2
- CUBN | c.6234T>G p.S2078R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100911955; called by muse, mutect2, varscan2
- CUBN | c.4149G>T p.Q1383H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100911956; called by muse, mutect2, varscan2
- CUX2 | c.4321A>T p.M1441L | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99918423; called by muse, mutect2, varscan2
- CYP1B1 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.692); catalogued as COSV99572542; called by muse, mutect2, varscan2
- CYP21A2 | c.1092G>T p.L364F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100925706; called by muse, mutect2, varscan2
- CYP7B1 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV100040585; called by muse, mutect2, varscan2
- CYRIA | c.315T>G p.S105R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as COSV100838192; called by muse, mutect2, varscan2
- DCAF8L1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV101491371, COSV101491427; called by muse, mutect2, varscan2
- DGKG | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as rs1269254883, COSV53966524, COSV99402255; called by muse, mutect2, varscan2
- DHDH | c.1004G>C p.*335Sext*5 | Nonstop Mutation (SNP) | VAF 29/97 reads (30%) | catalogued as COSV99668336; called by muse, mutect2, varscan2
- DLK1 | c.669C>A p.C223* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as rs1425335172, COSV100375006; called by muse, mutect2, varscan2
- DNAI3 | c.1312A>T p.K438* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99641245; called by muse, mutect2, varscan2
- DNAJA4 | c.841T>G p.L281V (on ENST00000343789; = p.L310V on NM_018602.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100655084, COSV100655151; called by muse, mutect2, varscan2
- DNMBP | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100142937; called by muse, mutect2, varscan2
- DNTT | c.400A>T p.S134C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.293); catalogued as COSV100960399; called by muse, mutect2, varscan2
- DOK7 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs1338126929, COSV100403096; called by muse, mutect2, varscan2
- DPEP1 | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs150374214, COSV99878247; called by muse, mutect2, varscan2
- DPYS | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372587190; called by muse, mutect2, varscan2
- DVL3 | c.1654G>T p.G552C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99490248; called by muse, mutect2, varscan2
- E2F7 | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100523247; called by muse, mutect2, varscan2
- ECT2 | c.1569A>G p.I523M (on ENST00000392692 / NM_001349098.2; = p.I492M on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.068); catalogued as rs1229703071, COSV99220797; called by muse, varscan2
- EDARADD | c.62-2A>T p.X21_splice (on ENST00000334232 / NM_145861.4; = p.X11_splice on NM_080738.4) | Splice Site (SNP) | VAF 35/96 reads (36%) | catalogued as COSV100512495; called by muse, mutect2, varscan2
- EDARADD | c.487C>A p.P163T (on ENST00000334232 / NM_145861.4; = p.P153T on NM_080738.4) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512496; called by muse, mutect2, varscan2
- EFCAB3 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100540002; called by muse, mutect2, varscan2
- EIF3E | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV55201495, COSV99622697; called by muse, mutect2, varscan2
- EIF4G1 | c.325-1G>T p.X109_splice | Splice Site (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100071369; called by muse, mutect2
- EIPR1 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV101181499, COSV66132163; called by muse, mutect2, varscan2
- ELF2 | c.946G>T p.D316Y (on ENST00000379550 / NM_001331036.2; = p.D256Y on NM_006874.4) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99642450; called by muse, mutect2, varscan2
- ELP4 | c.1088A>G p.D363G (on ENST00000350638; = p.D362G on NM_019040.5) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs1314127418, COSV100635043; called by muse, mutect2, varscan2
- EMILIN1 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100980104; called by muse, mutect2, varscan2
- EPB41L1 | c.1255C>A p.R419S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99148796; called by muse, mutect2, varscan2
- EPHA6 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV101060623, COSV67562008; called by muse, mutect2, varscan2
- EPHA6 | c.2232G>C p.L744F (on ENST00000389672 / NM_001080448.3; = p.L136F on NM_173655.4) | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101060624; called by muse, mutect2, varscan2
- EPHA7 | c.2057T>C p.M686T | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100993151; called by muse, mutect2, varscan2
- ERBB3 | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1323241399, COSV57261497; called by muse, mutect2, varscan2
- ERBB4 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs993251302, COSV99615122; called by muse, mutect2, varscan2
- ERCC4 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV100318592; called by muse, mutect2, varscan2
- ERGIC2 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 170/297 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs557188560, COSV100791924; called by muse, mutect2, varscan2
- ERMARD | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs752611527, COSV100824517; called by muse, mutect2, varscan2
- ETNK1 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 28/638 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs1414568335, COSV99860439; called by muse, mutect2
- ETV6 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67148966, COSV67155545; called by muse, mutect2, varscan2
- EXPH5 | c.2060A>C p.K687T | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99760813; called by muse, mutect2, varscan2
- FAM47C | c.1639C>A p.R547S | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.011); catalogued as COSV100792250, COSV63723454; called by muse, mutect2, varscan2
- FAT2 | c.5635G>A p.V1879I | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99941447; called by muse, mutect2, varscan2
- FAT3 | c.7434C>G p.S2478R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV99960918; called by muse, mutect2, varscan2
- FAT3 | c.8651A>T p.E2884V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99960921; called by muse, mutect2, varscan2
- FBXO11 | c.875C>T p.S292F (on ENST00000403359 / NM_001190274.2; = p.S208F on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs779725916, COSV100318913; called by muse, mutect2, varscan2
- FBXO30 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV52791713, COSV99394941; called by muse, mutect2, varscan2
- FCGBP | c.6692G>T p.G2231V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99660533; called by muse, mutect2, varscan2
- FCGBP | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1459472813; called by muse, mutect2, varscan2
- FCRL2 | c.555G>T p.R185S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100829799; called by muse, mutect2, varscan2
- FDXR | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs520611, COSV99501875; called by muse, mutect2, varscan2
- FERMT3 | c.1222G>T p.E408* (on ENST00000279227 / NM_178443.3; = p.E404* on NM_031471.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 153/427 reads (36%) | catalogued as COSV99656237; called by muse, mutect2, varscan2
- FGF4 | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99395209; called by muse, mutect2, varscan2
- FLRT3 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as rs1394764989, COSV99425948; called by muse, mutect2, varscan2
- FRAS1 | c.11829G>T p.L3943F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.346); catalogued as COSV99347624; called by muse, mutect2, varscan2
- FRMPD1 | c.505G>C p.G169R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100899232; called by muse, mutect2, varscan2
- FSHR | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1352532703, COSV58634873; called by muse, mutect2, varscan2
- GAB4 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV101271855, COSV68754668; called by muse, mutect2, varscan2
- GAB4 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV101271856; called by muse, mutect2, varscan2
- GABRA1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99195683; called by muse, mutect2, varscan2
- GABRB1 | c.200T>A p.I67N | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99779917; called by muse, mutect2, varscan2
- GABRD | c.1294C>A p.R432S | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1002172902, COSV101059502; called by muse, mutect2, varscan2
- GALC | c.1835-1G>C p.X612_splice | Splice Site (SNP) | VAF 28/127 reads (22%) | catalogued as COSV99728850; called by muse, mutect2, varscan2
- GALP | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV62000987; called by muse, mutect2, varscan2
- GATA3 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV100650774; called by muse, mutect2, varscan2
- GDAP2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1422384640, COSV101031813; called by muse, mutect2, varscan2
- GHR | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046037786, COSV100049677, COSV50107118; called by muse, mutect2, varscan2
- GLI2 | c.1933T>A p.S645T (on ENST00000361492 / NM_001374353.1; = p.S662T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100082166; called by muse, mutect2, varscan2
- GNL2 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs754672713, COSV100894944; called by muse, mutect2, varscan2
- GPAA1 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.373); catalogued as COSV100283947; called by muse, mutect2
- GPR63 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100013093; called by muse, mutect2, varscan2
- GRIN2B | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as COSV101662873; called by muse, mutect2, varscan2
- GRIN2D | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99615713; called by muse, mutect2, varscan2
- GRM5 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59596232, COSV59608030; called by muse, mutect2, varscan2
- H2BC6 | c.217C>A p.R73S | Missense Mutation (SNP) | VAF 105/149 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as COSV100534361; called by muse, mutect2, varscan2
- HAO1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV101113100; called by muse, mutect2, varscan2
- HCAR2 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100186397; called by muse, mutect2, varscan2
- HFM1 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 59/89 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99645199; called by muse, mutect2, varscan2
- HHIPL2 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV100596516; called by muse, mutect2, varscan2
- HK3 | c.1394del p.G465Efs*5 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs1342593054; called by mutect2, pindel, varscan2
- HMCN1 | c.3335C>A p.T1112N | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99623142; called by muse, mutect2, varscan2
- HMCN1 | c.9713T>G p.F3238C | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as rs1188853300, COSV99623143; called by muse, mutect2, varscan2
- HMCN1 | c.15706C>A p.Q5236K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV99623151; called by muse, mutect2, varscan2
- HNF4G | c.643G>T p.V215L (on ENST00000354370 / NM_001330561.2; = p.V262L on NM_004133.5) | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.452); catalogued as COSV100583961; called by muse, mutect2, varscan2
- HOOK3 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100294943; called by muse, mutect2, varscan2
- HOXB3 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV100290479, COSV57488208; called by muse, mutect2, varscan2
- HTR1A | c.525G>T p.W175C | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100108864; called by muse, mutect2, varscan2
- ICE1 | c.3056C>T p.T1019I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99663507; called by muse, mutect2, varscan2
- IFI44L | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100654845; called by muse, mutect2, varscan2
- IFT172 | c.1493A>T p.H498L | Missense Mutation (SNP) | VAF 133/241 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV99561599; called by muse, mutect2, varscan2
- IGF2 | c.547C>A p.R183S (on ENST00000434045 / NM_001127598.3; = p.R127S on NM_000612.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100323853; called by muse, mutect2, varscan2
- IGF2BP2 | c.180T>A p.G60= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100648810; called by muse, mutect2, varscan2
- IGHG1 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs1378532189; called by muse, mutect2, varscan2
- IGHV6-1 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs113325368; called by muse, mutect2, varscan2
- IGSF22 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766337479, COSV100078998; called by muse, mutect2, varscan2
- IGSF8 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100081446; called by muse, mutect2, varscan2
- IL1RAPL1 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1240596680, COSV100144753; called by muse, mutect2, varscan2
- IL22 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100048740; called by muse, mutect2, varscan2
- IL5RA | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764935099, COSV56524578, COSV99842592; called by muse, mutect2, varscan2
- IL9R | c.1177C>A p.L393M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV99729133; called by mutect2, varscan2
- INTU | c.2649T>G p.F883L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100080327; called by muse, mutect2, varscan2
- IPO11 | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV100320183; called by muse, mutect2, varscan2
- ITGBL1 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV101094977; called by muse, mutect2, varscan2
- ITPA | c.411G>A p.S137= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as rs1016862270, COSV101200047; called by muse, mutect2
- JAG2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs1444233637, COSV100077806; called by muse, mutect2, varscan2
- JAKMIP3 | c.2418G>A p.Q806= | Splice Region (SNP) | VAF 8/12 reads (67%) | catalogued as rs1231371013, COSV100058567; called by muse, mutect2, varscan2
- KALRN | c.4837G>T p.E1613* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99561796; called by muse, mutect2, varscan2
- KANSL1 | c.689A>T p.N230I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99293980; called by muse, mutect2, varscan2
- KATNA1 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100167590; called by muse, mutect2, varscan2
- KCTD8 | c.1103C>G p.T368S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV100759066; called by muse, mutect2, varscan2
- KDM5A | c.1548G>T p.E516D | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV101238563; called by muse, mutect2, varscan2
- KEAP1 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208201314, COSV50405151, COSV50635595; called by muse, mutect2, varscan2
- KIAA1549L | c.118G>T p.A40S (on ENST00000321505; = p.A337S on NM_012194.3) | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99682517; called by muse, mutect2, varscan2
- KIF18B | c.1223G>C p.G408A | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100191693; called by muse, mutect2, varscan2
- KIR3DL2 | c.1145C>G p.T382R | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as COSV99551697, COSV99551959; called by muse, varscan2
- KLHL42 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101179684; called by muse, mutect2
- KLK15 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV100032435; called by muse, mutect2, varscan2
- KRT1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV99358441; called by muse, mutect2, varscan2
- KRT20 | c.851T>A p.V284D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99391293; called by muse, mutect2, varscan2
- KRTAP10-11 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 86/141 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs782605215, COSV100551581; called by muse, mutect2, varscan2
- KRTAP5-3 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV101294484; called by muse, mutect2, varscan2
- KTN1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV101254933; called by muse, mutect2, varscan2
- L3MBTL3 | c.2168G>T p.C723F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100695668; called by muse, mutect2, varscan2
- LAD1 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs34525025, COSV100943761; called by muse, mutect2, varscan2
- LAMB3 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100620060; called by muse, mutect2, varscan2
- LARP4B | c.2059G>C p.A687P | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100294990, COSV60222975; called by muse, mutect2, varscan2
- LATS1 | c.623A>T p.Q208L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.13); catalogued as COSV99485099; called by muse, mutect2, varscan2
- LEMD3 | c.859A>T p.R287* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100384145; called by muse, mutect2, varscan2
- LEPR | c.130T>A p.Y44N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV100756222; called by muse, mutect2, varscan2
- LGI1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV101004339; called by muse, mutect2, varscan2
- LOXL2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1449432366, COSV101207706; called by muse, mutect2, varscan2
- LRIT1 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100927986; called by muse, mutect2, varscan2
- LRP1 | c.7663G>A p.D2555N | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99674060; called by muse, mutect2, varscan2
- LRP4 | c.4976C>A p.P1659H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV101066127; called by muse, mutect2, varscan2
- LRP4 | c.4975C>A p.P1659T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.422); catalogued as COSV101066132; called by muse, mutect2, varscan2
- LRPPRC | c.3650G>T p.G1217V | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV99579653; called by muse, mutect2, varscan2
- LRRC32 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs1259523703, COSV99476606; called by muse, mutect2, varscan2
- LRRIQ1 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1236254014, COSV101279307; called by muse, mutect2, varscan2
- LRRK1 | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as rs1428684279, COSV99437175, COSV99437437; called by muse, mutect2, varscan2
- LRRTM1 | c.1032C>A p.S344R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV54448372; called by muse, mutect2, varscan2
- LTBP1 | c.2500C>A p.L834M (on ENST00000404816 / NM_206943.4; = p.L508M on NM_000627.4) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); catalogued as COSV100616141; called by muse, mutect2, varscan2
- LUM | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV99898850; called by muse, mutect2, varscan2
- MAG | c.531C>A p.H177Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.233); catalogued as rs886516251, COSV100727562, COSV100728044; called by muse, mutect2
- MAGEB10 | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV100775098; called by muse, mutect2, varscan2
- MAGEB18 | c.1011C>A p.S337R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100305263; called by muse, mutect2, varscan2
- MAP2 | c.4480A>T p.T1494S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV99557423; called by muse, mutect2, varscan2
- MAP3K21 | c.1930T>A p.C644S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100786067; called by muse, mutect2, varscan2
- MATK | c.1351G>T p.G451C (on ENST00000310132 / NM_139355.3; = p.G452C on NM_002378.4) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100035777; called by muse, mutect2, varscan2
- MCM10 | c.1236T>G p.C412W (on ENST00000484800 / NM_182751.3; = p.C411W on NM_018518.5) | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101097868; called by muse, mutect2, varscan2
- MED13 | c.4091G>T p.G1364V | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67267659; called by muse, mutect2, varscan2
- METTL14 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.827); catalogued as COSV101183335; called by muse, varscan2
- METTL21C | c.605T>A p.L202Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57433348; called by muse, mutect2, varscan2
- MFSD6L | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | catalogued as COSV100319680; called by muse, mutect2, varscan2
- MIA2 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99697195; called by muse, mutect2, varscan2
- MIA2 | c.2321del p.P774Hfs*13 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as COSV54488877; called by mutect2, pindel, varscan2
- MICALL1 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99316947; called by muse, mutect2, varscan2
- MID1 | c.1540A>C p.K514Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV100452183; called by muse, mutect2, varscan2
- MIEF2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs374972603; called by muse, mutect2, varscan2
- MMAA | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99849586; called by muse, mutect2, varscan2
- MMAB | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749758687, CD023284, CM023192, COSV99904461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MN1 | c.3652T>G p.S1218A | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as COSV100179621; called by muse, mutect2, varscan2
- MOSPD2 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV100996634; called by muse, mutect2, varscan2
- MPP2 | c.514G>T p.G172* (on ENST00000461854 / NM_001278372.2; = p.G148* on NM_005374.5) | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as COSV99289836; called by muse, mutect2, varscan2
- MRC2 | c.4077G>T p.L1359F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.773); catalogued as rs1389790959, COSV100315710; called by muse, mutect2, varscan2
- MROH9 | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100882659; called by muse, mutect2, varscan2
- MS4A7 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV55730159; called by muse, mutect2, varscan2
- MUC16 | c.33209C>T p.T11070I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.918); catalogued as rs764651090, COSV101197725; called by muse, mutect2, varscan2
- MUC5AC | c.13928C>T p.S4643F | Missense Mutation (SNP) | VAF 59/83 reads (71%) | SIFT tolerated (0.07); catalogued as COSV100611293; called by muse, mutect2, varscan2
- MYBL2 | c.1827G>A p.P609= | Splice Region (SNP) | VAF 57/316 reads (18%) | catalogued as rs756988468, COSV99405937; called by muse, mutect2, varscan2
- MYBPC2 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV100731526, COSV63097769; called by muse, mutect2
- MYBPH | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99703756; called by muse, mutect2, varscan2
- MYF5 | c.399C>G p.S133R | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99953086; called by muse, mutect2, varscan2
- MYH1 | c.5011C>A p.L1671M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV99874711; called by muse, mutect2, varscan2
- MYH15 | c.2352A>T p.Q784H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99842022; called by muse, mutect2, varscan2
- MYH3 | c.5467C>G p.L1823V | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV99877607; called by muse, mutect2, varscan2
- MYLK3 | c.2373G>T p.Q791H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV101189038; called by muse, mutect2, varscan2
- MYO7B | c.3133C>A p.H1045N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1464956376, COSV101267833; called by muse, mutect2, varscan2
- NAA30 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV100035746; called by muse, mutect2, varscan2
- NAV3 | c.2864G>C p.G955A | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57084970, COSV99886244; called by muse, mutect2, varscan2
- NBAS | c.574A>T p.K192* | Nonsense Mutation (SNP) | VAF 47/203 reads (23%) | catalogued as COSV99866712; called by muse, mutect2, varscan2
- NCAN | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as rs745538431, COSV53047180; called by muse, mutect2, varscan2
- NDUFB5 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338267197, COSV99372422; called by muse, mutect2, varscan2
- NECAB2 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV100533793; called by muse, mutect2
- NFATC2 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769555895, COSV101043480; called by muse, mutect2, varscan2
- NFATC2 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV101043483; called by muse, mutect2, varscan2
- NID1 | c.2622C>A p.F874L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs151147666, COSV99936888; called by muse, mutect2, varscan2
- NID1 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99936890; called by muse, mutect2, varscan2
- NIPAL3 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.921); catalogued as rs777474294, COSV99135127; called by muse, mutect2, varscan2
- NLGN4X | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV99319559; called by muse, mutect2, varscan2
- NLRP10 | c.1357C>A p.Q453K | Missense Mutation (SNP) | VAF 75/109 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100149438, COSV100150045, COSV60780417; called by muse, mutect2, varscan2
- NLRP3 | c.2693G>T p.C898F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100275127; called by muse, mutect2, varscan2
- NMRK1 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312343821, COSV100737827; called by muse, mutect2, varscan2
- NNT | c.2903G>T p.R968L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332177629, COSV52922305, COSV99238290; called by muse, mutect2, varscan2
- NODAL | c.892-3_892-2del p.X298_splice | Splice Site (DEL) | VAF 18/83 reads (22%) | catalogued as rs774499735; called by mutect2, pindel, varscan2
- NOP56 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV100249911, COSV61391105; called by muse, mutect2, varscan2
- NPAP1 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1320003873, COSV100274659, COSV61507933; called by muse, varscan2
- NR0B1 | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV100973424; called by muse, mutect2, varscan2
- NR4A2 | c.717C>A p.H239Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as COSV100276890; called by muse, mutect2, varscan2
- NRXN1 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV100452821; called by muse, mutect2, varscan2
- NSG2 | c.290A>C p.Y97S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100292679; called by muse, mutect2
- NSG2 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100292681, COSV57459529; called by muse, mutect2
- NTHL1 | c.463C>T p.R155W (on ENST00000219066; = p.R147W on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1200691336, COSV54594916; ClinVar: uncertain significance; called by muse, mutect2
- NTS | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV55455891; called by muse, mutect2, varscan2
- NUP107 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV99971451; called by muse, mutect2, varscan2
- NUP210 | c.5372G>T p.G1791V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV99595454; called by muse, mutect2, varscan2
- NXF3 | c.1231del p.E411Sfs*3 | Frame Shift Del (DEL) | VAF 36/50 reads (72%) | catalogued as COSV67703382; called by mutect2, varscan2
- OBSCN | c.11890G>T p.G3964C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471482; called by muse, mutect2, varscan2
- OGA | c.2615-2A>C p.X872_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100761641; called by muse, mutect2, varscan2
- OLFM3 | c.1028G>T p.G343V (on ENST00000338858 / NM_001288821.1; = p.G323V on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58803627; called by muse, mutect2, varscan2
- OLFML2B | c.1904C>A p.A635D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs150749230, COSV99667952; called by muse, mutect2, varscan2
- OR10X1 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100936576, COSV100936628; called by muse, mutect2, varscan2
- OR1C1 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101376157, COSV68715581; called by muse, mutect2, varscan2
- OR2B11 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1467690874, COSV100275128; called by muse, mutect2, varscan2
- OR2G2 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.741); catalogued as COSV100189527; called by muse, mutect2, varscan2
- OR2L13 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV63549564; called by muse, mutect2, varscan2
- OR2T1 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63542114; called by muse, varscan2
- OR2T1 | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV63542479; called by muse, varscan2
- OR2T33 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100531509, COSV58817868; called by muse, mutect2, varscan2
- OR2T4 | c.632G>C p.C211S | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100822386, COSV63545148; called by muse, mutect2, varscan2
- OR2V2 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100079977; called by muse, mutect2, varscan2
- OR4Q3 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV59178245; called by muse, mutect2, varscan2
- OR52R1 | c.896C>A p.T299N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100617572, COSV61888897; called by muse, mutect2, varscan2
- OR5AP2 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100266009, COSV57257661, COSV57258537; called by muse, varscan2
- OR5D16 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV101003806; called by muse, mutect2, varscan2
- OR5M11 | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101602014; called by muse, mutect2, varscan2
- OR6F1 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.433); catalogued as COSV100128869, COSV100129051; called by muse, mutect2, varscan2
- OR6F1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100128845, COSV100128870; called by muse, mutect2, varscan2
- OR6K6 | c.146A>T p.H49L (on ENST00000368144; = p.H25L on NM_001005184.1) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV100933666; called by muse, mutect2, varscan2
- OR6N1 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV100625031, COSV58650751; called by muse, mutect2, varscan2
- OR7G2 | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.85); PolyPhen benign (0.196); catalogued as COSV100560282, COSV59688285; called by muse, mutect2, varscan2
- OR8B4 | c.659T>A p.I220K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100635756; called by muse, mutect2, varscan2
- OR8K5 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100537129, COSV57888827; called by muse, mutect2, varscan2
- P2RY4 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996951; called by muse, mutect2, varscan2
- PAGE2B | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100894278, COSV66611320; called by muse, mutect2, varscan2
- PAPPA2 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1326780859, COSV100866479, COSV62788373; called by muse, mutect2, varscan2
- PATJ | c.4384A>G p.I1462V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.078); catalogued as COSV100332945; called by muse, mutect2
- PCDH10 | c.1911G>T p.E637D | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1195914944, COSV99992773, COSV99993026; called by muse, mutect2, varscan2
- PCDH15 | c.4834A>T p.T1612S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.61); catalogued as COSV100902428; called by muse, mutect2, varscan2
- PCDHB15 | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV51229322, COSV99178809; called by muse, mutect2, varscan2
- PCLO | c.11244G>T p.R3748S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1486564998, COSV100426659, COSV61659566; called by muse, mutect2, varscan2
- PDE6A | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757735623, COSV99677678; called by muse, mutect2, varscan2
- PDIA4 | c.1702A>T p.S568C (on ENST00000286091 / NM_001371244.1; = p.S567C on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV99618216; called by muse, mutect2, varscan2
- PDK1 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1364417646, COSV99961048; called by muse, mutect2, varscan2
- PDYN | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV54101663, COSV99452612; called by muse, mutect2, varscan2
- PFKM | c.1988A>C p.Q663P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100402215; called by muse, mutect2, varscan2
- PHF20L1 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV99620170, COSV99620618; called by muse, mutect2, varscan2
- PIK3C2B | c.1756G>T p.V586L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100915963; called by muse, mutect2, varscan2
- PKD1 | c.7600A>T p.S2534C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV99237000; called by muse, mutect2, varscan2
- PKHD1L1 | c.7723G>T p.A2575S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV101005173; called by muse, mutect2, varscan2
- PLEC | c.6169C>T p.R2057W (on ENST00000322810 / NM_201380.4; = p.R1947W on NM_000445.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs781860739, COSV59618590; called by muse, mutect2, varscan2
- PLEKHA5 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.145); catalogued as COSV100163349; called by muse, mutect2, varscan2
- PLEKHM1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1468771543, COSV101378648; called by muse, mutect2
- PLG | c.2378A>T p.Y793F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.88); catalogued as COSV57520965; called by muse, mutect2, varscan2
- PNPLA1 | c.1169C>A p.P390H (on ENST00000394571 / NM_001374623.1; = p.P295H on NM_173676.2) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100462560; called by muse, mutect2, varscan2
- PNPLA5 | c.705A>G p.V235= | Splice Region (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99336433; called by muse, mutect2, varscan2
- POLH | c.113A>T p.Q38L | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100947596; called by muse, mutect2, varscan2
- PPFIA2 | c.2630G>T p.R877I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV100331366, COSV100333437; called by muse, mutect2, varscan2
- PPP1R32 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.62); PolyPhen probably damaging (1); catalogued as COSV58544138; called by muse, mutect2, varscan2
- PRG4 | c.2582C>A p.T861N | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV100798079; called by muse, mutect2, varscan2
- PRKCG | c.2078C>G p.P693R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); catalogued as COSV99668435; called by muse, mutect2, varscan2
- PRKD1 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100119109; called by muse, mutect2, varscan2
- PROSER3 | c.624C>T p.R208= | Splice Region (SNP) | VAF 60/69 reads (87%) | catalogued as rs774032469, COSV99994428; called by muse, mutect2, varscan2
- PRPS1L1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 91/132 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV101552910; called by muse, mutect2, varscan2
- PRSS55 | c.582G>T p.W194C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571129421, COSV100153590; called by muse, mutect2, varscan2
- PSG7 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs370284670; called by muse, mutect2, varscan2
- PSKH2 | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99404924; called by muse, mutect2, varscan2
- PTPRD | c.4834G>C p.A1612P | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61967220; called by muse, mutect2, varscan2
- PTPRT | c.1413G>C p.M471I | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100624600, COSV61982079; called by muse, mutect2, varscan2
- PXDNL | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1198584933, COSV100680718; called by muse, mutect2, varscan2
- PYGO1 | c.1193A>T p.D398V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV100114429; called by muse, mutect2, varscan2
- PYHIN1 | c.1001C>A p.T334K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63722127, COSV63722532; called by muse, mutect2, varscan2
- PYHIN1 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | PolyPhen possibly damaging (0.508); catalogued as COSV100932534; called by muse, mutect2, varscan2
- RAB11FIP2 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765549451, COSV100842984; called by muse, mutect2, varscan2
- RABEP2 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV100706778; called by muse, mutect2, varscan2
- RASGRF1 | c.1060C>A p.R354S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV101369504; called by muse, mutect2, varscan2
- RC3H2 | c.3117+1G>T p.X1039_splice (on ENST00000357244 / NM_001354479.2; = p.V1040L on NM_018835.4) | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100605266; called by muse, mutect2, varscan2
- RDX | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100562698; called by muse, mutect2, varscan2
- REM1 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99146676; called by muse, mutect2, varscan2
- RHBDD2 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99138158; called by muse, mutect2, varscan2
- ROBO2 | c.1711G>A p.V571M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs993855793, COSV100163710; called by muse, mutect2, varscan2
- ROBO4 | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs774678606, COSV100127234, COSV60623778; called by muse, mutect2, varscan2
- RRBP1 | c.2191G>A p.A731T (on ENST00000377813 / NM_001365613.2; = p.A298T on NM_004587.3) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV99853466; called by muse, mutect2, varscan2
- RSBN1 | c.1827G>T p.W609C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV99792742; called by muse, mutect2, varscan2
- RSF1 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100406811; called by muse, mutect2
- RTP5 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs764037906, COSV100574590; called by muse, mutect2, varscan2
- RYR2 | c.13363G>A p.E4455K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100767331; called by muse, mutect2
- RYR2 | c.14092C>A p.L4698M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs1325871553, COSV100767332; called by muse, mutect2, varscan2
- SAGE1 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV100186540; called by muse, mutect2, varscan2
- SCN1A | c.1060G>C p.A354P | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV100318986; called by muse, mutect2, varscan2
- SCN2A | c.3551T>A p.I1184K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV99329860; called by muse, mutect2, varscan2
- SCN9A | c.3411A>T p.E1137D (on ENST00000303354; = p.E1126D on NM_002977.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV100311068; called by muse, mutect2, varscan2
- SELP | c.2378C>A p.A793D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs182534305, COSV99738830; called by muse, mutect2, varscan2
- SEMA4D | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 87/105 reads (83%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV100357859, COSV59390977; called by muse, mutect2, varscan2
- SERPINB2 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1238883773, COSV99448595; called by muse, mutect2, varscan2
- SERPINE3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.192); catalogued as rs761778162, COSV68544947; called by muse, mutect2, varscan2
- SEZ6L | c.1515G>T p.R505S | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1330331452, COSV50658303, COSV99961164; called by muse, mutect2, varscan2
- SFXN1 | c.905T>A p.L302* | Nonsense Mutation (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100369165; called by muse, mutect2, varscan2
- SHOX2 | c.548G>T p.R183L (on ENST00000441443 / NM_006884.3; = p.R207L on NM_003030.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1465217056, COSV101273730; called by muse, mutect2, varscan2
- SIRPG | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV99403352; called by muse, mutect2, varscan2
- SLC12A3 | c.2181C>G p.A727= | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as COSV52633359, COSV99343739; called by muse, mutect2, varscan2
- SLC15A4 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.334); catalogued as COSV99903359; called by muse, mutect2, varscan2
- SLC16A5 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV100316924; called by muse, mutect2
- SLC22A16 | c.317G>T p.R106M | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100397068; called by muse, mutect2, varscan2
- SLC23A3 | c.1805G>T p.S602I (on ENST00000409878 / NM_001144889.2; = p.S485I on NM_144712.5) | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1346194899, COSV99840799; called by muse, mutect2, varscan2
- SLC34A1 | c.1301T>A p.V434E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100183731; called by muse, mutect2, varscan2
- SLC35C1 | c.1017G>A p.W339* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs1322531884, COSV100029322; called by muse, mutect2, varscan2
- SLC39A11 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99722088; called by muse, mutect2
- SLC45A2 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1329371090, COSV99672232; called by muse, mutect2, varscan2
- SLC4A5 | c.1310G>C p.G437A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV100697336; called by muse, mutect2, varscan2
- SLC4A8 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176378; called by muse, mutect2, varscan2
- SLC52A1 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99643292; called by muse, mutect2, varscan2
- SLC5A1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 63/92 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99833143; called by muse, mutect2, varscan2
- SLC5A2 | c.1258C>A p.R420S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1272328898, COSV100392957; called by mutect2, varscan2
- SLC66A2 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV100673723; called by muse, mutect2, varscan2
- SLC7A14 | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99200292; called by muse, mutect2, varscan2
- SLC8A1 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100244131; called by muse, mutect2, varscan2
- SLC9B1 | c.1472T>A p.L491Q | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56469269, COSV99599023; called by muse, mutect2
- SLCO1A2 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.94); catalogued as COSV100261231; called by muse, mutect2
- SLCO1B3 | c.1806G>A p.W602* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as rs550941268, COSV99680654; called by muse, mutect2
- SLCO1C1 | c.1441A>C p.K481Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.102); catalogued as rs1486713449, COSV99858317; called by muse, mutect2, varscan2
- SLITRK3 | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV99578275; called by muse, mutect2, varscan2
- SLITRK4 | c.654C>G p.S218R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100567103; called by muse, mutect2, varscan2
- SMAD3 | c.725A>C p.Q242P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.795); catalogued as COSV100528606; called by muse, mutect2, varscan2
- SMARCA4 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60785981, COSV60805231; called by muse, mutect2, varscan2
- SMYD3 | c.1141C>A p.L381I (on ENST00000490107 / NM_001375962.1; = p.L322I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV100830603; called by muse, mutect2, varscan2
- SNAP47 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100247861; called by muse, mutect2, varscan2
- SNTG1 | c.1359G>T p.L453F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99380702; called by muse, mutect2, varscan2
- SNTG2 | c.782C>G p.T261R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs530642242, COSV57972278; called by muse, mutect2, varscan2
- SOS2 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99365271; called by muse, mutect2, varscan2
- SOX5 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100505663; called by muse, mutect2, varscan2
- SPATA31E1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV100349828; called by muse, mutect2, varscan2
- SPATA5 | c.2250G>T p.L750F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99914544; called by muse, mutect2, varscan2
- SPEG | c.2573G>T p.R858L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100403088, COSV100403596; called by muse, mutect2, varscan2
- SPG11 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs1174016342, COSV99967900; called by muse, mutect2, varscan2
- SPTA1 | c.5024C>A p.S1675Y | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100934090, COSV63750363; called by muse, mutect2, varscan2
- SRGAP1 | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs774418285, COSV100754172; called by muse, mutect2, varscan2
- STAT3 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52884348, COSV52884550, COSV99232344; called by muse, mutect2, varscan2
- STON2 | c.2363G>T p.R788L (on ENST00000649389 / NM_001366849.2; = p.R731L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs747981712, COSV99964313, COSV99965039; called by muse, mutect2, varscan2
- STPG2 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV54783241, COSV54825855; called by muse, mutect2, varscan2
- STYXL2 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1221671020, COSV99608466; called by muse, mutect2, varscan2
- SULT1B1 | c.626T>A p.I209N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100150071; called by muse, mutect2, varscan2
- SYBU | c.1372C>A p.L458I (on ENST00000276646 / NM_001099754.2; = p.L457I on NM_017786.6) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV99405610; called by muse, mutect2, varscan2
- SYNE1 | c.2761C>A p.H921N (on ENST00000367255 / NM_182961.4; = p.H928N on NM_033071.3) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99551003; called by muse, mutect2, varscan2
- SYNJ2 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100839994, COSV62898973; called by muse, mutect2, varscan2
- TAB3 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as rs768438489, COSV99915632; called by muse, mutect2, varscan2
- TAF5L | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs755691299, COSV99272526; called by muse, mutect2, varscan2
- TANGO6 | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99935528; called by muse, mutect2, varscan2
- TBC1D1 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs747602498, COSV99790297; called by muse, mutect2, varscan2
- TBX18 | c.1477T>A p.S493T | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100858379; called by muse, mutect2, varscan2
- TDRD1 | c.1574C>A p.A525E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs753980626, COSV99313890; called by muse, mutect2, varscan2
- TDRD9 | c.3949G>T p.D1317Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100174552; called by muse, mutect2, varscan2
- TEKT3 | c.1156A>T p.I386F | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100106712; called by muse, mutect2, varscan2
- TENM1 | c.4090T>A p.L1364I | Missense Mutation (SNP) | VAF 55/76 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1172787815, COSV100948858; called by muse, mutect2, varscan2
- TEP1 | c.6616G>T p.G2206W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201529942, COSV99401490; called by muse, mutect2, varscan2
- TEX13B | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 83/103 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV100258232; called by muse, mutect2, varscan2
- THSD1 | c.880C>A p.L294M | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV99318649; called by muse, mutect2, varscan2
- TLN1 | c.4021G>T p.A1341S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.206); catalogued as COSV100147216; called by muse, mutect2, varscan2
- TLN2 | c.5513A>T p.K1838M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV60888738; called by muse, mutect2, varscan2
- TLR3 | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99710767; called by muse, mutect2, varscan2
- TLR4 | c.1703C>A p.P568Q (on ENST00000355622 / NM_138554.5; = p.P528Q on NM_003266.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100842626; called by muse, mutect2, varscan2
- TMF1 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1300918913, COSV68373908; called by muse, mutect2, varscan2
- TNK2 | c.2482G>C p.A828P | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs552313951, COSV100360912, COSV57377180; called by muse, mutect2, varscan2
- TNR | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99687068; called by muse, mutect2, varscan2
- TPR | c.6958C>T p.P2320S | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV100798080; called by muse, mutect2, varscan2
- TPR | c.6957A>T p.Q2319H | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100798081; called by muse, mutect2, varscan2
- TRAF3IP3 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as rs747009027, COSV99159976; called by muse, mutect2, varscan2
- TRAM1 | c.123+2T>G p.X41_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV51599022, COSV99140696; called by mutect2, varscan2
- TREX2 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 99/134 reads (74%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100443935, COSV57849083; called by muse, mutect2, varscan2
- TRIM58 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100824822, COSV63572148; called by muse, mutect2, varscan2
- TRIM69 | c.1264A>T p.T422S (on ENST00000329464 / NM_182985.5; = p.T263S on NM_080745.5) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.165); catalogued as COSV100274135; called by muse, mutect2, varscan2
- TRIO | c.5032C>T p.R1678* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs749963113, COSV60095677; called by muse, mutect2, varscan2
- TRMO | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV100908850, COSV64292434; called by muse, mutect2, varscan2
- TRPS1 | c.64G>T p.E22* (on ENST00000220888 / NM_001330599.2; = p.E35* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99627912; called by muse, mutect2, varscan2
- TSHZ1 | c.1624G>T p.D542Y (on ENST00000580243 / NM_001308210.2; = p.D497Y on NM_005786.6) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100433341; called by muse, mutect2, varscan2
- TSHZ2 | c.1334C>A p.P445Q | Missense Mutation (SNP) | VAF 128/187 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV100295220, COSV61588424; called by muse, mutect2, varscan2
- TSPYL6 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.027); catalogued as COSV100336205; called by muse, mutect2, varscan2
- TTN | c.23471A>T p.Q7824L (on ENST00000591111; = p.Q6897L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | PolyPhen benign (0.007); catalogued as COSV100591354; called by muse, mutect2, varscan2
- TTYH1 | c.682T>A p.C228S | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV100001699; called by muse, mutect2, varscan2
- UBE4A | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99347790; called by muse, mutect2, varscan2
- UBN2 | c.762_764del p.E254del | In Frame Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs774724044; called by pindel, varscan2
- UGT2B10 | c.868-1G>A p.X290_splice | Splice Site (SNP) | VAF 11/191 reads (6%) | catalogued as rs782107811, COSV99607792; called by muse, mutect2
- UGT2B11 | c.1256C>A p.T419K | Missense Mutation (SNP) | VAF 125/173 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV101485210; called by muse, mutect2, varscan2
- UGT2B17 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1406846291, COSV100497150; called by muse, mutect2, varscan2
- UNC13A | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV99406857; called by muse, mutect2, varscan2
- USP9Y | c.2549G>T p.R850L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100168162; called by muse, mutect2, varscan2
- VEGFC | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54595012; called by muse, mutect2, varscan2
- VPS13C | c.6100C>T p.Q2034* (on ENST00000644861 / NM_020821.3; = p.Q1991* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99826659; called by muse, mutect2, varscan2
- VSTM4 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV100251175; called by muse, mutect2, varscan2
- WT1 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1193052708, COSV100186680, COSV60086637; called by muse, mutect2, varscan2
- YTHDF3 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV101572350; called by muse, mutect2, varscan2
- ZBTB11 | c.2124G>T p.Q708H | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs1480843496, COSV100465033; called by muse, mutect2, varscan2
- ZBTB2 | c.1318A>C p.M440L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100287465; called by muse, mutect2, varscan2
- ZBTB21 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 102/142 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as rs757855811, COSV60404561; called by muse, mutect2, varscan2
- ZFHX4 | c.7415C>T p.S2472F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs536193735, COSV99255008; called by muse, mutect2, varscan2
- ZFP30 | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100665779; called by muse, mutect2, varscan2
- ZFP42 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100478558, COSV58819515; called by muse, mutect2, varscan2
- ZNF345 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100080114; called by muse, mutect2, varscan2
- ZNF407 | c.5145G>T p.K1715N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1319360304, COSV100224439; called by muse, mutect2, varscan2
- ZNF442 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99664214; called by muse, mutect2, varscan2
- ZNF471 | c.585A>T p.K195N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1162684635, COSV100340310; called by muse, mutect2, varscan2
- ZNF492 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71762203; called by mutect2, varscan2
- ZNF516 | c.2527G>T p.G843W | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101487185, COSV71587512; called by muse, mutect2, varscan2
- ZNF536 | c.2845G>T p.V949F | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.133); catalogued as COSV100834522; called by muse, mutect2, varscan2
- ZNF606 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV100357018; called by muse, mutect2, varscan2
- ZNF606 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100008548; called by muse, mutect2, varscan2
- ZNF611 | c.28A>T p.R10W | Missense Mutation (SNP) | VAF 139/174 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100159940; called by muse, mutect2, varscan2
- ZNF672 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1346657213, COSV100129029; called by muse, mutect2, varscan2
- ZNF746 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100502342; called by muse, mutect2, varscan2
- ZNF804A | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100166040, COSV56458123; called by muse, mutect2, varscan2
- ZNF98 | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100757253; called by mutect2, varscan2
- ZSCAN5B | c.1328A>T p.Y443F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.113); catalogued as COSV100627834; called by muse, mutect2, varscan2
- CDH4 | c.2073del p.I691Mfs*56 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | called by mutect2, pindel, varscan2
- CDIPT | c.90del p.C31Afs*40 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by pindel, varscan2*
- FRG2C | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); called by muse, mutect2
- GRIK4 | c.65dup p.H23Afs*35 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.3162del p.N1055Ifs*49 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by mutect2, pindel, varscan2
- HTR5A | c.969_998del p.L324_F333del | In Frame Del (DEL) | VAF 12/119 reads (10%) | called by mutect2, pindel
- IGHE | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- IGHG1 | c.977T>A p.L326Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHG1 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- IGKV2-24 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LAMA1 | c.6472del p.L2158Sfs*49 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- LHX1 | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- LRRC66 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- MARK1 | c.98dup p.S34Vfs*3 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- MIA2 | c.1807_1808delinsT p.R603Lfs*3 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by pindel, varscan2*
- MRPL19 | c.276_277delinsA p.F92Lfs*3 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by pindel, varscan2*
- MYO19 | c.805A>T p.R269W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCDHGA12 | c.295del p.A99Pfs*6 | Frame Shift Del (DEL) | VAF 45/81 reads (56%) | called by mutect2, pindel, varscan2
- PLAA | c.372del p.T125Hfs*15 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- SIK2 | c.1021del p.R341Gfs*35 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3649C>G p.L1217V | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- SPATA31A3 | c.3649C>G p.L1217V | Missense Mutation (SNP) | VAF 97/115 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- SPATA31A3 | c.2737C>A p.P913T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by mutect2, varscan2
- SQLE | c.44dup p.K16Efs*71 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- SRP68 | c.1780del p.A594Pfs*46 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- SYTL2 | c.2339del p.P780Qfs*19 (on ENST00000528231 / NM_001162951.2; = p.P756Qfs*19 on NM_032943.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/76 reads (46%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.9C>G p.C3W | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TRBV6-1 | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VN1R5 | c.976C>G p.Q326E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ACP1 | c.252C>T p.A84= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99681425; called by muse, mutect2, varscan2
- ACSF3 | c.1491C>T p.P497= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100441016; called by muse, mutect2, varscan2
- ADAMTS16 | c.645G>T p.G215= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV56989394, COSV99939744; called by muse, mutect2, varscan2
- ADCY4 | c.753G>A p.Q251= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV53474630, COSV99352883; called by muse, mutect2, varscan2
- AGAP3 | c.93G>T p.A31= (on ENST00000622464; = p.A67= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99880166; called by muse, mutect2
- ANGEL2 | c.969G>T p.T323= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs148141428, COSV100853904; called by muse, mutect2, varscan2
- ANGPTL3 | c.1266A>T p.A422= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99222399; called by muse, mutect2, varscan2
- ANO2 | c.310C>A p.R104= (on ENST00000356134 / NM_001278597.3; = p.R108= on NM_001278596.3) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100499530; called by muse, mutect2, varscan2
- ARHGAP32 | c.1122G>T p.L374= (on ENST00000310343 / NM_001378025.1; = p.L25= on NM_014715.4) | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as rs746397942, COSV100086728; called by muse, mutect2, varscan2
- ARMH4 | c.1348C>T p.L450= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99957485; called by muse, mutect2, varscan2
- BHLHE23 | c.435G>T p.L145= (on ENST00000370346; = p.L161= on NM_080606.4) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100947570; called by muse, mutect2, varscan2
- BRIP1 | c.1566A>T p.S522= | Silent (SNP) | VAF 57/227 reads (25%) | catalogued as COSV99369018; called by muse, mutect2, varscan2
- BTNL8 | c.1071G>A p.V357= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99180411; called by muse, mutect2, varscan2
- C14orf39 | c.1404A>G p.E468= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100407164; called by muse, mutect2, varscan2
- C1QL4 | c.342G>T p.A114= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1455183301, COSV99226633, COSV99227077; called by muse, mutect2, varscan2
- C1orf100 | c.51G>A p.P17= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as rs377260797; called by muse, mutect2, varscan2
- C2CD3 | c.4644A>C p.S1548= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100486161; called by muse, mutect2, varscan2
- CACNA1C | c.5143C>A p.R1715= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs373996684, COSV100219354; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1E | c.2755C>A p.R919= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs769941881, COSV62394979, COSV62397581; called by muse, mutect2, varscan2
- CALCRL | c.96T>A p.I32= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV101130863; called by muse, mutect2, varscan2
- CCDC57 | c.1875G>A p.E625= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs1175172016, COSV100492362; called by muse, mutect2, varscan2
- CCDC9 | c.1356C>T p.A452= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99699492; called by muse, mutect2, varscan2
- CD226 | c.288G>T p.R96= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1568208573, COSV99710674; called by muse, mutect2, varscan2
- CDCA5 | c.636C>A p.P212= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs777095627, COSV99297633, COSV99297671; called by muse, mutect2, varscan2
- CDH7 | c.150G>T p.V50= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100541259, COSV100541396; called by muse, mutect2, varscan2
- CDH9 | c.294C>A p.G98= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV50276625, COSV99141286; called by muse, mutect2, varscan2
- CHRM5 | c.90C>A p.V30= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV67247716; called by muse, mutect2, varscan2
- CHRNA4 | c.1701G>A p.A567= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs1373364724, COSV64719012; called by muse, mutect2
- CLEC3A | c.549T>A p.A183= (on ENST00000651443; = p.A174= on NM_005752.6) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100222030; called by muse, mutect2, varscan2
- COL12A1 | c.8187G>A p.E2729= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs755878621, COSV100485239; called by muse, mutect2
- COL19A1 | c.1242A>T p.T414= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100504911; called by muse, mutect2, varscan2
- COL9A3 | c.810G>A p.R270= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as COSV100673260, COSV100673413; called by muse, mutect2, varscan2
- CSMD1 | c.8553C>A p.S2851= (on ENST00000520002; = p.S2850= on NM_033225.6) | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1232255427, COSV100142375, COSV59347336; called by muse, mutect2, varscan2
- CSMD2 | c.4872G>T p.V1624= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99585094; called by muse, mutect2, varscan2
- CST2 | c.177T>A p.T59= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100491084; called by muse, mutect2, varscan2
- CSTF1 | c.531G>A p.T177= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs141380576; called by muse, mutect2, varscan2
- CTNNA2 | c.60G>T p.R20= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100781391; called by muse, mutect2, varscan2
- CTNND2 | c.1695G>T p.S565= | Silent (SNP) | VAF 72/144 reads (50%) | catalogued as rs778117375, COSV100470763; called by muse, mutect2, varscan2
- CTNND2 | c.534G>T p.L178= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100470769; called by muse, mutect2, varscan2
- DCAF12L1 | c.1290G>C p.A430= | Silent (SNP) | VAF 40/57 reads (70%) | catalogued as rs755096870, COSV64421685; called by muse, mutect2, varscan2
- DCDC1 | c.2076A>G p.P692= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100662565; called by muse, mutect2
- DISP2 | c.2169C>A p.V723= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1276318244, COSV99139649; called by muse, mutect2
- DNAH17 | c.9165G>T p.T3055= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV101101233; called by muse, mutect2, varscan2
- DNAH5 | c.5205C>T p.S1735= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV99444049; called by muse, mutect2, varscan2
- DNAH9 | c.8137C>A p.R2713= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs760609171, COSV52348055, COSV99303461; called by muse, mutect2, varscan2
- DSCAML1 | c.4485C>G p.S1495= (on ENST00000321322; = p.S1435= on NM_020693.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100354279, COSV100357164; called by muse, mutect2, varscan2
- ESRP2 | c.1546C>A p.R516= (on ENST00000565858 / NM_001365264.1; = p.R506= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99251029; called by muse, mutect2, varscan2
- FAM135B | c.966G>T p.L322= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV52732335, COSV99418870; called by muse, mutect2, varscan2
- FAM43B | c.93G>T p.S31= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV100261441, COSV100261460; called by muse, mutect2, varscan2
- FAM71F1 | c.579G>T p.L193= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs1310694909, COSV100170816; called by muse, mutect2, varscan2
- FBLL1 | c.747G>T p.V249= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1294774468, COSV100606118; called by muse, mutect2, varscan2
- FBN1 | c.4464G>T p.V1488= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100353904; called by muse, mutect2, varscan2
- FLG | c.7531A>C p.R2511= | Silent (SNP) | VAF 57/547 reads (10%) | catalogued as COSV100910385; called by muse, mutect2, varscan2
- FNBP4 | c.654C>T p.G218= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs181295298; called by muse, mutect2, varscan2
- FPR2 | c.252C>A p.S84= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV100389069; called by muse, mutect2, varscan2
- GAA | c.1479C>T p.P493= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV100162838; called by muse, mutect2, varscan2
- GHR | c.1509G>T p.P503= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100049675; called by muse, mutect2, varscan2
- GIMAP6 | c.717C>A p.T239= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV100188050; called by muse, mutect2, varscan2
- GLIPR1 | c.435T>C p.D145= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs774095859, COSV99875451; called by muse, mutect2, varscan2
- GTF2F1 | c.1128G>T p.P376= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs773356588, COSV101080985; called by muse, mutect2, varscan2
- HCN1 | c.1485G>T p.V495= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as rs747328003, COSV100298034; called by muse, mutect2, varscan2
- HECW1 | c.2250C>T p.P750= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs369845470; called by muse, mutect2, varscan2
- HERC1 | c.4332C>A p.S1444= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV101496286; called by muse, mutect2, varscan2
- HEY2 | c.804C>G p.A268= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV100856275, COSV64240839; called by muse, mutect2, varscan2
- HMCN1 | c.11433C>A p.T3811= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs1425496568, COSV99623148; called by muse, mutect2, varscan2
- HMGCS2 | c.855C>A p.G285= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV101024674; called by muse, mutect2, varscan2
- HSPA9 | c.1764C>T p.I588= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99785197; called by muse, mutect2, varscan2
- IFT140 | c.2817G>T p.S939= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99559643; called by muse, mutect2, varscan2
- IGFN1 | c.3348C>T p.A1116= (on ENST00000295591 / NM_001367841.1; = p.A3573= on NM_001164586.2) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99810916; called by muse, mutect2, varscan2
- IKZF1 | c.456C>T p.A152= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100497865; called by muse, mutect2, varscan2
- IL3RA | c.543C>T p.H181= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV100452133; called by muse, mutect2, varscan2
- INSL5 | c.9C>T p.G3= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1253425356, COSV100455375; called by muse, mutect2, varscan2
- IRF2BP1 | c.1515G>T p.L505= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1170766744, COSV100138789; called by muse, mutect2, varscan2
- KCNF1 | c.57C>A p.A19= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1200055606, COSV99705486; called by muse, mutect2, varscan2
- KCNJ1 | c.798G>A p.L266= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV100131204; called by muse, mutect2, varscan2
- KIAA0319L | c.2130A>G p.A710= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100356708; called by muse, mutect2, varscan2
- KRT33B | c.844C>T p.L282= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV99290444; called by muse, mutect2, varscan2
- LAMA1 | c.6936G>T p.G2312= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101054694; called by muse, mutect2, varscan2
- LAMC3 | c.2583C>T p.D861= | Silent (SNP) | VAF 39/52 reads (75%) | catalogued as COSV100735870; called by muse, mutect2, varscan2
- LHX6 | c.759G>C p.A253= (on ENST00000373755 / NM_001242334.2; = p.A282= on NM_014368.5) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100493195; called by muse, mutect2, varscan2
- LMTK3 | c.1224C>A p.L408= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1485595089, COSV99539862; called by muse, mutect2
- LRRC32 | c.591C>A p.P197= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99476608; called by muse, mutect2, varscan2
- MAGEB6B | c.810C>A p.L270= | Silent (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- MAP3K19 | c.606C>A p.G202= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100207959; called by muse, mutect2, varscan2
- MRTFB | c.630G>T p.A210= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100370771, COSV57956206; called by muse, mutect2, varscan2
- MTOR | c.6543G>A p.E2181= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs17229235, COSV100815656; called by muse, mutect2, varscan2
- MUC16 | c.13386A>T p.T4462= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV101197726; called by muse, mutect2, varscan2
- MYBPC1 | c.2379G>C p.T793= (on ENST00000550270 / NM_206820.2; = p.T800= on NM_002465.4) | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100637692; called by muse, mutect2, varscan2
- MYT1L | c.99C>T p.T33= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1438389601, COSV101218325; called by muse, mutect2, varscan2
- NCAM1 | c.618C>A p.V206= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV100376894, COSV57524564; called by muse, mutect2, varscan2
- NCAN | c.2934G>A p.P978= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs760959295, COSV99386420; called by muse, mutect2, varscan2
- NCKAP5 | c.2034C>A p.P678= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100489670; called by muse, mutect2, varscan2
- NCKAP5 | c.1776C>T p.H592= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1428905103, COSV100489672; called by muse, mutect2, varscan2
- NDN | c.264G>T p.P88= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1243330148, COSV100086180; called by muse, mutect2, varscan2
- NIBAN1 | c.1119G>T p.V373= | Silent (SNP) | VAF 61/249 reads (24%) | catalogued as COSV100836160, COSV62284830; called by muse, mutect2, varscan2
- NLRP10 | c.1164C>T p.Y388= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs140749197; called by muse, mutect2, varscan2
- NRXN1 | c.1203G>T p.T401= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100452823; called by muse, mutect2, varscan2
- NXPE1 | c.1038C>A p.G346= (on ENST00000424269; = p.G204= on NM_152315.5) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99319825; called by muse, mutect2, varscan2
- OGDHL | c.2445G>T p.V815= | Silent (SNP) | VAF 70/199 reads (35%) | catalogued as COSV100934174; called by muse, mutect2, varscan2
- OPRK1 | c.189G>C p.T63= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV99653640; called by muse, mutect2, varscan2
- OR14C36 | c.537C>T p.I179= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs372326031; called by muse, mutect2, varscan2
- OR2M5 | c.777C>T p.Y259= | Silent (SNP) | VAF 77/352 reads (22%) | catalogued as rs1477866442, COSV100822719; called by muse, mutect2, varscan2
- OR4P4 | c.321C>A p.G107= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100111514; called by muse, mutect2, varscan2
- OR5H2 | c.492T>C p.H164= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100788607; called by mutect2, varscan2
- OTOP2 | c.843T>C p.P281= | Silent (SNP) | VAF 59/280 reads (21%) | catalogued as COSV100508755, COSV58883622; called by muse, mutect2, varscan2
- PAK1IP1 | c.1137G>A p.L379= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV101093315; called by muse, mutect2, varscan2
- PAK5 | c.1230C>T p.T410= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100781007; called by muse, mutect2, varscan2
- PDE1B | c.81C>T p.P27= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as COSV99672067; called by muse, mutect2, varscan2
- PKNOX2 | c.102C>A p.A34= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100019840, COSV53544788; called by muse, mutect2, varscan2
- PKP2 | c.1083G>A p.E361= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV99297125; called by muse, mutect2, varscan2
- PLA2G4C | c.57C>T p.A19= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs749663476, COSV62787591; called by muse, mutect2, varscan2
- POU3F4 | c.276G>C p.A92= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100937144, COSV100937157; called by muse, mutect2, varscan2
- POU6F1 | c.1578C>T p.N526= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV100374710; called by muse, mutect2, varscan2
- PPAT | c.396G>A p.R132= | Silent (SNP) | VAF 48/65 reads (74%) | catalogued as COSV99946996; called by muse, mutect2, varscan2
- PRKCB | c.1020C>A p.T340= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100331906, COSV100335924; called by muse, mutect2, varscan2
- PTGER2 | c.309G>T p.A103= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs938381548, COSV99817275; called by muse, mutect2, varscan2
- PTGER2 | c.489C>A p.V163= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99817277; called by muse, mutect2, varscan2
- PTPRB | c.1860C>A p.S620= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as rs374912045, COSV99718282; called by muse, mutect2, varscan2
- PZP | c.1830T>C p.S610= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99735711; called by muse, mutect2
- RBM19 | c.615G>T p.L205= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV99925405; called by muse, mutect2, varscan2
- RELN | c.495C>A p.G165= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs768834240, COSV100631828, COSV100632056; called by muse, mutect2, varscan2
- RIMS2 | c.2610A>G p.P870= (on ENST00000666250 / NM_001348490.2; = p.P678= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99155711; called by muse, mutect2, varscan2
- ROR2 | c.420G>T p.G140= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100995414, COSV65224061; called by muse, mutect2, varscan2
- RPL5 | c.312G>A p.L104= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV100240229; called by muse, mutect2, varscan2
- SCAF11 | c.291T>C p.Y97= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs1414193298, COSV99873908; called by muse, mutect2, varscan2
- SH3TC1 | c.1851G>T p.R617= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs1282269853, COSV99794308; called by muse, mutect2, varscan2
- SIPA1L2 | c.5154C>T p.I1718= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs775669622, COSV53383572; called by muse, varscan2
- SIPA1L3 | c.3540G>T p.T1180= | Silent (SNP) | VAF 51/212 reads (24%) | catalogued as rs372129344, COSV99726991; called by muse, mutect2, varscan2
- SLC12A5 | c.1632C>T p.F544= (on ENST00000454036 / NM_001134771.2; = p.F521= on NM_020708.5) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99715166; called by muse, mutect2, varscan2
- SLC25A52 | c.226C>A p.R76= (on ENST00000672005; = p.R66= on NM_001034172.4) | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs142346377, COSV52501662; called by muse, varscan2
- SLC25A52 | c.153C>T p.A51= (on ENST00000672005; = p.A41= on NM_001034172.4) | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV52502660; called by muse, varscan2
- SLC34A1 | c.1302G>T p.V434= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100183733; called by muse, mutect2, varscan2
- SLC35F1 | c.1038C>A p.I346= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100837403; called by muse, mutect2, varscan2
- SLCO1B3 | c.282G>T p.P94= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53932888, COSV99680650; called by muse, mutect2, varscan2
- SMCO3 | c.363G>A p.L121= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99660514; called by muse, mutect2, varscan2
- SMOC1 | c.819G>C p.L273= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100734243; called by muse, mutect2, varscan2
- SPTA1 | c.4755G>C p.L1585= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV100934091, COSV100934672; called by muse, mutect2, varscan2
- SRPRB | c.138G>T p.A46= | Silent (SNP) | VAF 43/53 reads (81%) | catalogued as rs777146219, COSV101524149; called by muse, mutect2, varscan2
- ST3GAL1 | c.1008C>T p.I336= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100171755; called by muse, mutect2, varscan2
- TAAR9 | c.219G>T p.S73= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV101453275, COSV101453354; called by muse, mutect2, varscan2
- TAB3 | c.747G>T p.P249= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs201728663, COSV99915630, COSV99916829; called by muse, mutect2, varscan2
- TCIM | c.27C>T p.A9= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs1563486507, COSV100249516; called by muse, mutect2, varscan2
- TELO2 | c.1929G>T p.P643= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99247948; called by muse, mutect2, varscan2
- TMUB1 | c.348G>T p.V116= | Silent (SNP) | VAF 73/196 reads (37%) | catalogued as COSV99879496; called by muse, mutect2, varscan2
- TNPO1 | c.2208C>T p.A736= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV100472936; called by muse, mutect2, varscan2
- TNR | c.2713C>A p.R905= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV99687070; called by muse, mutect2, varscan2
- TRPV6 | c.1584C>T p.G528= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs777597496, COSV100844078; called by muse, mutect2, varscan2
- TSPAN16 | c.654G>A p.L218= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100368177; called by muse, mutect2, varscan2
- TTN | c.57189T>C p.H19063= (on ENST00000591111; = p.H11639= on NM_003319.4) | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as rs749153813, COSV100591350; called by muse, mutect2, varscan2
- TTN | c.8577A>T p.S2859= (on ENST00000591111; = p.S2813= on NM_003319.4) | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as COSV100591356; called by muse, mutect2, varscan2
- USH2A | c.4542C>A p.T1514= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100228062; called by muse, mutect2, varscan2
- VIM | c.438G>C p.L146= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99812834; called by muse, mutect2, varscan2
- XPOT | c.1047A>G p.G349= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs777518529, COSV100225292; called by muse, mutect2, varscan2
- ZC4H2 | c.531C>T p.A177= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100564687; called by muse, mutect2, varscan2
- ZIC3 | c.414G>A p.G138= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99798205; called by muse, mutect2, varscan2
- ZNF518A | c.3465T>A p.T1155= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100283299; called by muse, mutect2, varscan2
- ZNF547 | c.819T>C p.C273= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV99987706; called by muse, mutect2
- ZNF746 | c.243G>T p.L81= | Silent (SNP) | VAF 98/202 reads (49%) | catalogued as rs1562994183, COSV100502343; called by muse, mutect2, varscan2
- ZP4 | c.1248C>T p.R416= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1240739722, COSV100850509; called by muse, mutect2, varscan2
- ACTN1 | c.2361+519G>T | Intron (SNP) | VAF 17/54 reads (31%) | catalogued as rs1196262183, COSV99517105; called by muse, mutect2, varscan2
- AL109984.1 | n.186+4901T>C | Intron (SNP) | VAF 35/114 reads (31%) | catalogued as COSV100800836; called by muse, mutect2, varscan2
- BRD9 | c.718-15A>T | Intron (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100056764; called by muse, mutect2, varscan2
- DENND10P1 | n.1213C>G | RNA (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- FAM169B | n.694T>A | RNA (SNP) | VAF 25/43 reads (58%) | catalogued as rs758849987, COSV100259618; called by muse, mutect2, varscan2
- GRM7 | c.2698+6121C>A | Intron (SNP) | VAF 54/186 reads (29%) | catalogued as COSV100735385; called by muse, mutect2, varscan2
- IGSF1 | c.667+41C>A | Intron (SNP) | VAF 22/22 reads (100%) | catalogued as COSV100811769; called by muse, mutect2, varscan2
- LDB2 | c.-1del | 5'UTR (DEL) | VAF 9/30 reads (30%) | catalogued as COSV100452745; called by mutect2, pindel, varscan2
- MIR1-1HG-AS1 | n.651C>G | RNA (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+9458C>A | Intron (SNP) | VAF 64/89 reads (72%) | catalogued as COSV99783328; called by muse, mutect2, varscan2
- OR2W5 | n.786G>T | RNA (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- SPATA8 | n.221A>C | RNA (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100138857; called by muse, mutect2, varscan2
- VWA2 | c.2122+56A>T | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100073240; called by muse, mutect2
